Gene-level copy-number profile of tumor specimen TCGA-AA-3982-01A from TCGA case TCGA-AA-3982, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.6 years (27,608 days).
Specimen TCGA-AA-3982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fc11105d-3c10-4912-9763-f234ca782f06.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3982-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1e9bad8-664d-4870-92df-b0066edadb56

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 729; copy number 2: 7,580; copy number 3: 28,359; copy number 4: 18,222; copy number 5: 1,668; copy number 6: 909; copy number 8: 1,785; copy number 9: 279; copy number 10: 280; copy number 13: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3982-01A-02D-1018-01): tumor purity 0.54, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,352 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:127,215,127–129,952,960, 93 genes, copy number 8 (broad region; genes not listed).
- chr7:129,954,693–129,954,794, 1 gene, copy number 8: Y_RNA.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 8–10 (broad region; genes not listed).
- chr14:22,086,407–22,530,378, 83 genes, copy number 8 (broad region; genes not listed).
- chr20:28,563,850–35,092,807, 177 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:37,903,111–41,712,600, 79 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:45,975,249–61,083,750, 299 genes, copy number 8–13 (broad region; genes not listed).
- chr20:61,267,525–61,437,630, 3 genes, copy number 9: AL365229.1, BX640515.1, AL160412.1.
- chr20:63,009,383–64,313,132, 83 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
